Somatic mutation profile of tumor specimen TCGA-A7-A4SC-01A (aliquot TCGA-A7-A4SC-01A-12D-A25Q-09) from TCGA case TCGA-A7-A4SC, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 63.0 years (23,008 days).
Specimen TCGA-A7-A4SC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 31432192-438f-42ae-bbb5-ac36377331fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A7-A4SC-10A (Blood Derived Normal), aliquot TCGA-A7-A4SC-10A-01D-A25Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4ab79912-82f8-44ea-a69a-2a89a8de07b3

The open-access MAF lists 29 somatic variants for this specimen: 24 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 19, Silent 5, Frame Shift Del 3, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 19/91 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACTL9 | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as rs782182119, COSV61006158; called by muse, mutect2, varscan2
- AGO2 | c.2140C>T p.R714W | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866981753, COSV55048605, COSV55051361; called by muse, mutect2, varscan2
- ANK2 | c.4280G>A p.R1427Q | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754722115, COSV52144785; called by muse, mutect2, varscan2
- BTBD11 | c.2128C>T p.R710C (on ENST00000280758 / NM_001018072.2; = p.R247C on NM_001017523.2) | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs776541174, COSV55016703; called by muse, mutect2, varscan2
- CACNA1E | c.6374G>T p.G2125V (on ENST00000367573 / NM_001205293.3; = p.G2082V on NM_000721.4) | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as COSV62412317; called by muse, mutect2, varscan2
- CDH1 | c.863_864del p.D288Gfs*4 | Frame Shift Del (DEL) | VAF 8/52 reads (15%) | catalogued as COSV55738669; called by mutect2, pindel, varscan2
- CDKL3 | c.1015A>C p.S339R | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV54744162; called by muse, mutect2, varscan2
- CHD7 | c.1537A>T p.T513S | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as COSV71110009, COSV71113547; called by muse, mutect2, varscan2
- CSNK1E | c.29G>T p.R10L | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.82); catalogued as COSV63291966; called by muse, mutect2, varscan2
- CYP2A13 | c.593T>G p.F198C | Missense Mutation (SNP) | VAF 38/160 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57839576; called by muse, varscan2
- ERICH5 | c.244C>A p.Q82K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.022); catalogued as COSV59316814; called by muse, mutect2, varscan2
- F13B | c.1040C>A p.A347E | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.22); catalogued as COSV66375296; called by muse, mutect2, varscan2
- HK1 | c.850G>A p.G284R | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.992); catalogued as COSV53864212; called by muse, mutect2, varscan2
- LYSMD1 | c.14C>T p.S5F | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs200029870, COSV54861179; called by muse, mutect2, varscan2
- MYH9 | c.4975G>A p.A1659T | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.045); catalogued as rs371410108; called by muse, mutect2, varscan2
- NOTCH2 | c.4888C>G p.R1630G | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as COSV56687234, COSV56701592; called by muse, mutect2
- NRK | c.3509G>T p.G1170V | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV54603713; called by muse, mutect2, varscan2
- SEL1L2 | c.1948-2A>T p.X650_splice | Splice Site (SNP) | VAF 8/33 reads (24%) | catalogued as COSV53156270; called by muse, mutect2, varscan2
- ZNF333 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.18); catalogued as rs199652435, COSV52887852; called by muse, mutect2, varscan2
- ZNF8 | c.196C>T p.P66S | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.984); catalogued as COSV52189183; called by muse, mutect2, varscan2
- ZP4 | c.1311G>A p.P437= | Splice Region (SNP) | VAF 8/49 reads (16%) | catalogued as rs746266633, COSV63910808, COSV63913201; called by muse, mutect2, varscan2
- CBY1 | c.378del p.K126Nfs*15 | Frame Shift Del (DEL) | VAF 19/67 reads (28%) | called by mutect2, pindel, varscan2
- PLCL2 | c.1660del p.Y554Ifs*8 (on ENST00000615277 / NM_001144382.2; = p.Y428Ifs*8 on NM_015184.5) | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | called by mutect2, pindel, varscan2
- HOXA3 | c.804C>T p.P268= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as COSV57828293; called by muse, mutect2, varscan2
- KLHL15 | c.1062G>A p.P354= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as rs1212658604, COSV60140370; called by muse, mutect2, varscan2
- PYGB | c.2118C>G p.A706= | Silent (SNP) | VAF 24/86 reads (28%) | catalogued as rs199844284, COSV53821850; called by muse, mutect2, varscan2
- RIMBP2 | c.1947G>T p.S649= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV55481073; called by muse, mutect2, varscan2
- ZNF846 | c.705C>T p.F235= | Silent (SNP) | VAF 20/82 reads (24%) | catalogued as COSV67412476; called by muse, mutect2, varscan2
